CCDI case PBCSHW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/78c2cde7-c194-46df-a023-b12a3beaebdc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Short bones of lower limb and associated joints; Age at diagnosis: 14.2 years (5,185 days).

Biospecimens (3 samples)
- Sample 0DY77V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY78A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY78R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
